Somatic mutation profile of tumor specimen MMRF_1380_1_BM_CD138pos (aliquot MMRF_1380_1_BM_CD138pos_T1_KAS5U_L00657) from MMRF case MMRF_1380, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,039 days).
Specimen MMRF_1380_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e035e3a3-e410-4079-bc72-5251c850856e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1380_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1380_2_PB_Whole_C2_KBS5U_L03497; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ed3f643-cfe3-47c8-9b04-c27f1d44a5ad

The open-access MAF lists 52 somatic variants for this specimen: 20 protein-altering or splice-affecting, 10 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, 3'UTR 10, Intron 5, 5'UTR 3, Frame Shift Del 2, RNA 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.6797A>G p.Q2266R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); catalogued as rs759145806, COSV101330102; called by muse, mutect2, varscan2
- CCDC180 | c.3601G>A p.V1201M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759178274; called by muse, mutect2, varscan2
- COX10 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 76/76 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs757204220, COSV55402311; called by muse, mutect2, varscan2
- DUSP2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs144192490; called by muse, mutect2, varscan2
- GALNT11 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs865813933; called by muse, mutect2, varscan2
- HOXB1 | c.728A>G p.N243S | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781620828; called by muse, mutect2, varscan2
- PCDH7 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1209188261; called by muse, mutect2, varscan2
- SYPL1 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as rs767856183, COSV50579412; called by muse, mutect2, varscan2
- EFCAB10 | c.111A>C p.K37N | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GYPE | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- HROB | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- HSPA8 | c.650_665del p.F217* | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | called by mutect2, pindel*, varscan2
- IGSF1 | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 48/50 reads (96%) | SIFT tolerated (0.08); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- OR4A16 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SATB2 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SERPINI1 | c.550_553del p.V184Ifs*32 | Frame Shift Del (DEL) | VAF 37/72 reads (51%) | called by mutect2, pindel, varscan2
- TOGARAM1 | c.2491T>C p.S831P | Missense Mutation (SNP) | VAF 89/94 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VCAM1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ZNF850 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZW10 | c.1247C>A p.T416N | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2
- ATP8B4 | c.513G>A p.T171= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as rs536808455, COSV52710214, COSV52716049; called by muse, mutect2, varscan2
- DNAH17 | c.5458C>T p.L1820= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV101103480; called by muse, mutect2, varscan2
- GRIK4 | c.1239C>A p.L413= | Silent (SNP) | VAF 56/131 reads (43%) | called by muse, mutect2, varscan2
- H2AC17 | c.369C>T p.S123= | Silent (SNP) | VAF 83/163 reads (51%) | called by muse, mutect2, varscan2
- ITPR3 | c.5673C>T p.F1891= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- KCND3 | c.21C>T p.A7= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- LGI2 | c.52C>T p.L18= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2
- MTTP | c.2658G>A p.P886= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as rs368664326; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM140 | c.441G>A p.P147= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs199612642, COSV51967751; called by muse, mutect2, varscan2
- ZNF414 | c.219C>T p.D73= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2
- A2M | chr12:9064606 G>C | 3'Flank (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- ABHD17C | c.*408G>A | 3'UTR (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020969 C>A | 5'Flank (SNP) | VAF 45/92 reads (49%) | catalogued as COSV55849224, COSV55851032; called by muse, mutect2, varscan2
- CHD1L | c.1086-28C>T | Intron (SNP) | VAF 27/51 reads (53%) | catalogued as rs1253919598; called by muse, mutect2, varscan2
- DCAF17 | c.-188C>T | 5'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- DCC | c.*915C>T | 3'UTR (SNP) | VAF 60/98 reads (61%) | catalogued as rs1340666407; called by muse, mutect2, varscan2
- FGF3 | c.*44C>T | 3'UTR (SNP) | VAF 30/62 reads (48%) | catalogued as rs781981072; called by muse, mutect2, varscan2
- GPAT3 | c.1126-20_1126-19insG | Intron (INS) | VAF 4/31 reads (13%) | catalogued as rs568328440; called by pindel, varscan2
- GTF3C5 | c.*360C>T | 3'UTR (SNP) | VAF 29/56 reads (52%) | catalogued as rs554864738; called by muse, mutect2, varscan2
- HEMGN | c.*567T>C | 3'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- HEMK1 | c.*1264A>G | 3'UTR (SNP) | VAF 5/23 reads (22%) | catalogued as rs963994928; called by muse, mutect2, varscan2
- KNOP1P1 | n.194A>G | RNA (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- MIR4510 | n.44_46del | RNA (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- MUC6 | c.-25C>T | 5'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, varscan2
- NAA25 | c.*2206_*2208del | 3'UTR (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- NANS | c.870+644G>A | Intron (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- NUDT21 | c.317+58A>T | Intron (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- PPP2R5C | c.93+2603_93+2604insA | Intron (INS) | VAF 6/30 reads (20%) | called by pindel, varscan2
- RNF14 | c.*1253C>T | 3'UTR (SNP) | VAF 43/76 reads (57%) | catalogued as rs1414727391; called by muse, mutect2, varscan2
- SECTM1 | c.-35A>T | 5'UTR (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- SSTR1 | c.*861C>G | 3'UTR (SNP) | VAF 25/26 reads (96%) | called by muse, mutect2, varscan2
- TBPL2 | c.*296G>A | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
